Gene-level copy-number profile of tumor specimen ALCH-B1KC-TTP1-A from ALCHEMIST case ALCH-B1KC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 56.9 years (20,789 days).
Specimen ALCH-B1KC-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9a8ae51c-4202-42e8-a041-eec7abfbeba4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1KC-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/1970bb9d-a36d-43e2-96f2-05cda0d4f320

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 11; copy number 2: 3,991; copy number 3: 145; copy number 4: 48,672; copy number 5: 11; copy number 6: 3,485; copy number 7: 850; copy number 8: 233; copy number 9: 17; copy number 10: 31; copy number 11: 701; copy number 13: 37; copy number 14: 61; copy number 21: 3; copy number 22: 24; copy number 30: 39; copy number 39: 28; copy number 40: 2; copy number 43: 2; copy number 49: 22.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:4,246,339–4,247,358, 1 gene (within-gene range 0–2): AC005578.1.
- chr21:7,744,962–8,701,562, 29 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 967 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:139,561,570–140,479,536, 16 genes, copy number 9: HIPK2, TBXAS1, PARP12, KDM7A, Y_RNA, KDM7A-DT, RNU6-797P, RNU1-58P, AC005377.1, PPP1R2P6, SLC37A3, RNA5SP247, RNA5SP248, RAB19, AC069335.1, MKRN1.
- chr7:142,111,749–142,272,235, 4 genes, copy number 13: MGAM2, MOXD2P, PRSS58, TRY2P.
- chr13:39,209,116–45,083,125, 105 genes, copy number 10–11 (within-gene range 2–11) (broad region; genes not listed).
- chr13:54,440,704–114,337,626, 623 genes, copy number 10–11 (broad region; genes not listed).
- chr19:19,255,638–19,256,141, 1 gene, copy number 9 (within-gene range 2–9): AC138430.2.
- chr20:19,756,390–22,966,063, 60 genes, copy number 13–43: AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1, CFAP61, AL035454.1, AL049648.1, RPL17P1, CFAP61-AS1, RN7SL690P, AL161658.1, INSM1, RALGAPA2, EIF4E2P1, LLPHP1, RN7SL607P, MRPS11P1, AL133465.1, LINC00237, AL121759.2, RPL24P2, KIZ, RNA5SP477, AL121759.1, KIZ-AS1, RPS15AP1, ZNF877P, AL117332.1, XRN2, NKX2-4, AL158013.1, RN7SKP140, AL133325.1, AL133325.3, GSTM3P1, NKX2-2, NKX2-2-AS1, AL133325.2, LINC01727, LINC01726, AL121590.1, PAX1, SLC25A6P1, RPL41P1, AL109807.1, LINC01432, AL035258.1, LINC01427, AL049737.1, AL121912.1, AL133464.1, LINC00261, FOXA2, LNCNEF, LINC01747, AL158175.1, KRT18P3, CYB5AP4, AL353132.1.
- chr20:23,918,538–26,251,546, 61 genes, copy number 14 (broad region; genes not listed).
- chr20:30,484,925–30,816,274, 4 genes, copy number 11: 5_8S_rRNA, ANKRD20A21P, U6, RNA5SP528.
- chr20:51,386,957–57,712,780, 93 genes, copy number 13–49 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
